Somatic mutation profile of tumor specimen TCGA-LK-A4NW-01A (aliquot TCGA-LK-A4NW-01A-11D-A34C-32) from TCGA case TCGA-LK-A4NW, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.0 years (21,922 days).
Specimen TCGA-LK-A4NW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d00cefdc-ec7d-431b-ac2b-38569ce90ffa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4NW-10A (Blood Derived Normal), aliquot TCGA-LK-A4NW-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda3ca77-41d7-406b-8d08-013cfc76a1b0

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 3, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLCN | c.1300+1G>A p.X434_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as rs879255676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56232919, COSV56236792; called by muse, mutect2, varscan2
- CCDC185 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs777062819, COSV64821275; called by muse, mutect2, varscan2
- HELZ | c.3196C>T p.R1066W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs753412795; called by muse, mutect2, varscan2
- TMC4 | c.304G>T p.A102S (on ENST00000617472 / NM_001145303.3; = p.A96S on NM_144686.4) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.381); catalogued as COSV55477378; called by muse, varscan2
- ADGRG5 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- C1orf141 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM160B2 | c.1312_1314del p.I438del | In Frame Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- FBH1 | c.1052T>C p.V351A (on ENST00000362091 / NM_178150.3; = p.V402A on NM_032807.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- FBN2 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1D-16 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IL4R | c.2113G>C p.D705H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM2B | c.3506G>T p.S1169I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LGALS3BP | c.275A>C p.Q92P | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OTOP1 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SLC39A6 | c.1688A>T p.H563L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- XPOT | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- CENPF | c.2296C>T p.L766= | Silent (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- CFAP157 | c.759G>A p.E253= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2
- KIR2DL4 | c.1212C>G p.T404= (on ENST00000396284; = p.T330= on NM_001080770.2) | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- OR51B5 | c.430C>T p.L144= | Silent (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- PTPRS | c.2229G>A p.S743= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- MANSC1 | c.*1G>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
